Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AQ-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site Code: breast, NOS C50.9

12/21/10 *ku*

Final Diagnosis

Breast, right, wide local excision: Infiltrating ductal carcinoma, Nottingham grade III (of III), [tubules 3/3, nuclei 3/3, mitoses 3/3; Nottingham score 9/9], forming a 3.5 x 2.5 x 2.5 cm mass [AJCCpT2]. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.5 cm medial margin).

Lymph nodes, right axillary sentinel, excision: Multiple (6) right axillary sentinel lymph nodes with blue dye are negative for metastatic carcinoma (AJCCpN0(i-) (sn)]. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Lymph node, right axillary non-sentinel, excision: A single right axillary non-sentinel lymph node identified is negative for tumor.

Seen in consultation with Dr.

IPNA Discrepancy		☒

Source: NCI Genomic Data Commons file 1b116a6e-ae22-4e04-b179-19025e935310 (TCGA-AR-A1AQ.FC236604-AAE5-4394-9D39-270FFEFB635A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).